Surgical pathology report (de-identified scan), TCGA case TCGA-44-2656, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-2656-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Right upper lobe
- B. 2R
- C. 4R
- D. Station 7
- E. Station 9

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer.
POST-OP DIAGNOSIS: Same.

GROSS DESCRIPTION

A. Received fresh labeled "right upper lobe" is a 252 gm., 19.5 x 13.0 x 3.5 cm. lobectomy specimen with attached 1 cm. in length, 1.7 x 0.9 cm. in diameter bronchial stump. There is a moderately well circumscribed, 2.0 x 1.5 x 1.2 cm. pale tan to gray black tumor mass within the inferolateral aspect. The lesion approaches the pleura. A portion of tumor and a portion of normal are submitted for tissue procurement as requested. A possible secondary lesion measuring 0.8 x 0.7 x 0.4 cm. is present along the pleural aspect of the lung, approximately 3.5 cm. from the primary lesion (see block 7 and 8). The remaining parenchyma is spongiform tan pink-red with diffuse anthracosis. No additional mass lesion or abnormalities identified. Five gray black tissues in keeping with lymph nodes measuring up to 1.6 cm. in greatest dimension are recovered from the hilum. Representative sections are submitted in 13 blocks as labeled. RS-13

BLOCK SUMMARY: 1 - bronchial stump margin; 2 - vascular margins; 3 through 5 - tumor to inked pleural surface; 6 - tumor to normal parenchyma; 7 and 8 - secondary ? lesion; 9 through 11 - random normal; 12 - four whole lymph nodes; 13 - one bisected lymph node.

GROSS DESCRIPTION

B. Received fresh, subsequently fixed in formalin, labeled "2R", is a 2.2 x 1.2 x 0.7 cm., yellow, lobular, fatty tissue fragment, which is entirely submitted in one cassette. AS-1

C. Received fresh, subsequently fixed in formalin, labeled "4R", are multiple black-pink-red, irregular, soft tissue fragments, 1.2 x 0.7 x 0.3 cm. The specimens are entirely submitted in one cassette. AS-1

D. Received fresh, subsequently fixed in formalin, labeled "Station 7", are three black-pink, irregular, soft to friable tissue fragments, which range from 1.2 cm. to 2.2 cm. in

[page 2 of 3]
greatest dimension. The specimens are entirely submitted in one cassette. AS-1

E. Received fresh, subsequently fixed in formalin, labeled

"Station 9", is a 1.2 x 0.7 x 0.3 cm., black-pink, irregular to soft tissue fragment, which is entirely submitted in one cassette. AS-1

MICROSCOPIC DESCRIPTION

A.

Histologic type: Adenocarcinoma.

Histologic grade: Moderately differentiated.

Primary tumor: Primary tumor measures 2.0 cm. but invades the visceral pleura.

Margins of resection: Uninvolved.

Direct extension of tumor: Not identified.

Venous (large vessel) invasion: Identified.

Arterial (large vessel) invasion: Identified.

Lymphatic (small vessel) invasion: Not identified.

Regional lymph nodes (pN): None positive (pN0).

Distant metastasis (pM): Cannot be evaluated by this specimen

MICROSCOPIC DESCRIPTION

Other findings: There is an intraparenchymal lymph node containing granulomatous inflammation in A9. Stains for AFB and fungal organisms are negative. Additionally in blocks A7 and A8 (grossly identified lesion) biopsy site changes are present. There are 9 lymph nodes and main specimen negative for tumor.

B. The 2R lymph nodes demonstrates 6 lymph nodes negative for metastasis.

C. The 4R lymph nodes demonstrates 2 lymph nodes negative for metastasis.

D. The station 7 lymph nodes demonstrates 3 lymph nodes negative for metastasis. Granulomatous inflammation is present. No organisms are detected on AFB or fungal stains.

E. The station 9 lymph nodes demonstrates 1 node negative for metastasis.

4X2 3x3, 17x4

[page 3 of 3]
DIAGNOSIS

- A. Lung, right upper lobe, resection:
- Adenocarcinoma, moderately differentiated, 2.0 cm. surgical margins uninvolved.
- Nine lymph nodes with no evidence of metastasis.
- B. 2R lymph nodes, resection:
- No evidence of metastasis the six lymph nodes (0/6).
- C. 4R lymph nodes, resection:
- Two lymph nodes with no evidence of metastasis (0/2).
- D. Station 7 lymph nodes, resection:
- No evidence of metastasis in three lymph nodes (0/3).
- Granulomatous inflammation.
- E. Station 9 lymph node, metastasis:
- One lymph node with no evidence of metastasis (0/1).

DIAGNOSIS

Source: NCI Genomic Data Commons file d5535d0f-2bb0-4731-9f3f-30b4149ed19b (TCGA-44-2656.3C7E7F0D-F1B6-42CF-895E-DF6CC52F4C2A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).